TCGA case TCGA-2Y-A9GZ — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0e8c3831-def9-4efa-9f93-8942072d6a77

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 82 years; Vital status: Dead; Days to death: 848 days (2.3 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 82.4 years (30,082 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib Tosylate; Days to treatment start: 719 days (2.0 years); Days to treatment end: 842 days (2.3 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 84.3 years (30,801 days); Days to diagnosis: 719 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 719 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 719 days (2.0 years).
- Days to follow up: 848 days (2.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prothrombin Time 9.9 Seconds [Blood test normal range lower: 8.3; Blood test normal range upper: 11.5].
- Albumin 4.5 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Total Bilirubin 0.7 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.3].
- Platelets 318 (unit not recorded by GDC) [Blood test normal range lower: 143; Blood test normal range upper: 382].
- Creatinine 1.1 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.5].
- Alpha Fetoprotein 7 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 7].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: HBV Core Antibody / Hepatitis C Antibody.
- Timepoint category: Initial Diagnosis; Weight: 51 kg; Height: 153 cm; BMI: 21.8.

Family history
- Relatives with cancer history count: 4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2Y-A9GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-2Y-A9GZ-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2Y-A9GZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2Y-A9GZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: HBV Core Antibody.
- Drug treatment: Pharmaceutical therapy drug name: Naxavar.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 848 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 848 days; disease-free interval: event (new tumor event after initially disease-free), 719 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 719 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2Y-A9GZ-01A-11D-A38W-01): tumor purity 0.78, ploidy 3.42, whole-genome doublings 1.
